Somatic mutation profile of tumor specimen TCGA-SX-A71R-01A (aliquot TCGA-SX-A71R-01A-12D-A33Q-10) from TCGA case TCGA-SX-A71R, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 51.3 years (18,742 days).
Specimen TCGA-SX-A71R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff53efe3-2a3b-41b4-bdca-1da497ef6577.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A71R-10A (Blood Derived Normal), aliquot TCGA-SX-A71R-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/173851cd-6de9-4d05-8a67-b38a6fe010c5

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP3 | c.3656G>T p.G1219V | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1458041095, COSV53354196; called by muse, varscan2
- ARHGEF17 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV99734813; called by muse, mutect2, varscan2
- CANT1 | c.1087T>G p.S363A | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100185150; called by muse, mutect2
- CHD8 | c.5666G>A p.R1889H (on ENST00000646647 / NM_001170629.2; = p.R1610H on NM_020920.4) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777867742, COSV63036682; called by muse, mutect2, varscan2
- CYP4F3 | c.101T>G p.I34S | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV99657735; called by muse, mutect2
- DNAJC18 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV100122044; called by muse, mutect2, varscan2
- EPHB6 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 79/110 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs764313153, COSV67419824; called by muse, mutect2, varscan2
- EVI2B | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.341); catalogued as COSV100445367; called by muse, mutect2, varscan2
- GSTA1 | c.590T>G p.F197C | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100575430; called by muse, mutect2, varscan2
- HERC6 | c.2678C>A p.P893H | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99986308; called by muse, mutect2, varscan2
- HNRNPD | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV100002716; called by muse, mutect2, varscan2
- KCNT2 | c.2347A>C p.N783H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV99651227; called by muse, mutect2, varscan2
- MASP2 | c.1253G>C p.W418S | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101280004; called by muse, mutect2, varscan2
- MROH8 | c.2002T>C p.S668P | Missense Mutation (SNP) | VAF 96/160 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs762962737, COSV99456573; called by muse, mutect2, varscan2
- MRPL32 | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99785665; called by muse, mutect2, varscan2
- MTM1 | c.185G>T p.R62I | Missense Mutation (SNP) | VAF 256/278 reads (92%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as CM1513747, COSV100080146, COSV100080283; called by muse, mutect2, varscan2
- NEU1 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99998560; called by muse, varscan2
- NRXN1 | c.3835A>C p.N1279H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV100639729; called by muse, mutect2, varscan2
- PCSK7 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV100309152; called by muse, mutect2, varscan2
- RAN | c.481T>G p.F161V | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV99619584; called by muse, mutect2, varscan2
- RRAGA | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1273272529, COSV65844179; called by muse, mutect2, varscan2
- SEMA3B | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs1287935229, COSV100312687; called by muse, mutect2, varscan2
- SKIV2L | c.1910G>A p.S637N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100952572; called by muse, mutect2, varscan2
- SLC4A7 | c.561A>G p.A187= | Splice Region (SNP) | VAF 38/76 reads (50%) | catalogued as COSV99839097; called by muse, mutect2, varscan2
- SLC7A5 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99878958; called by muse, mutect2, varscan2
- SMARCA4 | c.3601G>C p.V1201L | Missense Mutation (SNP) | VAF 77/151 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV100758100; called by muse, mutect2, varscan2
- STRN3 | c.1346T>A p.V449E (on ENST00000357479 / NM_001083893.2; = p.V365E on NM_014574.4) | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100670258; called by muse, mutect2, varscan2
- SWAP70 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.278); catalogued as COSV100013498; called by muse, mutect2, varscan2
- TENM3 | c.6225G>A p.M2075I | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs759907837, COSV101304838; called by muse, mutect2, varscan2
- TRPM1 | c.2618T>A p.L873* | Nonsense Mutation (SNP) | VAF 38/70 reads (54%) | catalogued as COSV99855263; called by muse, mutect2, varscan2
- TTC3 | c.1053A>T p.E351D | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV100694966; called by muse, mutect2, varscan2
- VEPH1 | c.1623A>G p.I541M | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100747313; called by muse, mutect2, varscan2
- XRRA1 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100369569; called by muse, mutect2
- CACNA1E | c.2201_2207dup p.S736Rfs*101 | Frame Shift Ins (INS) | VAF 29/72 reads (40%) | called by mutect2, varscan2
- DENND1B | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 52/128 reads (41%) | called by muse, mutect2, varscan2
- IMPDH1 | c.1422_1427del p.L475_S476del (on ENST00000470772 / NM_001142573.2; = p.L561_S562del on NM_000883.4) | In Frame Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- MAML2 | c.578del p.N193Mfs*29 | Frame Shift Del (DEL) | VAF 54/139 reads (39%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.6055del p.V2019Sfs*27 | Frame Shift Del (DEL) | VAF 28/71 reads (39%) | called by mutect2, pindel, varscan2
- ALKBH5 | c.450C>T p.P150= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as rs756287332, COSV99230953; called by muse, mutect2, varscan2
- BCDIN3D | c.712T>C p.L238= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV100445433; called by muse, mutect2, varscan2
- CCDC59 | c.84G>A p.R28= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs751217910, COSV99810495; called by muse, mutect2, varscan2
- FBP2 | c.627T>A p.I209= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100942038; called by muse, mutect2, varscan2
- GPAT3 | c.468A>G p.L156= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs745536952, COSV100022701; called by muse, mutect2, varscan2
- KCNH8 | c.1350C>T p.F450= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as COSV100108283; called by muse, mutect2, varscan2
- MORC3 | c.388T>C p.L130= | Silent (SNP) | VAF 60/140 reads (43%) | catalogued as COSV101264822; called by muse, mutect2, varscan2
- NAT9 | c.477T>C p.L159= | Silent (SNP) | VAF 102/168 reads (61%) | catalogued as COSV99379826; called by muse, mutect2, varscan2
- PCDHGA4 | c.1359A>T p.V453= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV99529730; called by muse, mutect2, varscan2
- SON | c.5352A>G p.S1784= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as COSV99276702; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 5/46 reads (11%) | catalogued as rs201441562; called by pindel, varscan2
